Somatic mutation profile of tumor specimen ALCH-B0CI-TTP1-A (aliquot ALCH-B0CI-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,958 days).
Specimen ALCH-B0CI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d40d7f9b-fc41-4e56-a4a4-12e1ed0797cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CI-NB1-A (Blood Derived Normal), aliquot ALCH-B0CI-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bd7bc52-fd6c-46d2-b0c8-6439185a3b54

The open-access MAF lists 205 somatic variants for this specimen: 147 protein-altering or splice-affecting, 26 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 26, Intron 19, Nonsense Mutation 9, Frame Shift Del 6, 3'UTR 5, 5'UTR 3, RNA 3, Splice Site 2, In Frame Del 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 124/407 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 115/685 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSS1 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as rs554617131; called by muse, mutect2, varscan2
- ADGRL3 | c.2198C>T p.A733V (on ENST00000506720 / NM_001322402.2; = p.A665V on NM_015236.6) | Missense Mutation (SNP) | VAF 105/635 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.743); catalogued as rs768679654, COSV101547182, COSV72231399; called by muse, mutect2, varscan2
- AFM | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 84/404 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936316986; called by muse, mutect2, varscan2
- AHNAK2 | c.13555G>T p.D4519Y | Missense Mutation (SNP) | VAF 77/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60925013; called by muse, mutect2, varscan2
- ANK2 | c.7552G>C p.E2518Q | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV52172183; called by muse, mutect2, varscan2
- ASTN1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760958680, COSV56070701; called by muse, mutect2, varscan2
- ATF4 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 70/504 reads (14%) | catalogued as rs1569026789; called by muse, mutect2, varscan2
- ATM | c.4201T>A p.L1401I | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.091); catalogued as rs587779838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACH2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 73/459 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs368297011; called by muse, mutect2, varscan2
- CALML4 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV51117635; called by muse, mutect2, varscan2
- CENPF | c.8848C>T p.P2950S | Missense Mutation (SNP) | VAF 125/705 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100871971; called by muse, mutect2, varscan2
- COL5A1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 65/453 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.105); catalogued as rs777789161, COSV65676491; called by muse, mutect2, varscan2
- CSRNP1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 89/401 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs369362214; called by muse, mutect2, varscan2
- CYP11B1 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 62/447 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs1296927504; called by muse, mutect2, varscan2
- ESYT3 | c.1551_1553del p.F518del | In Frame Del (DEL) | VAF 38/274 reads (14%) | catalogued as rs373950279; called by pindel, varscan2
- GALNT13 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.776); catalogued as COSV101223014; called by muse, mutect2, varscan2
- HTR1A | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 197/900 reads (22%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs775618804; called by muse, mutect2, varscan2
- IL17A | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 79/420 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs755641354; called by muse, mutect2, varscan2
- KCNH7 | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as CM150738, COSV59811906; called by muse, mutect2, varscan2
- KHDC1L | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 81/446 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV64893247; called by muse, mutect2, varscan2
- MDGA1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs1163229019, COSV51799446; called by muse, mutect2, varscan2
- MKI67 | c.6574G>C p.E2192Q | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs139058203, COSV64075605; called by muse, mutect2
- MROH2B | c.4368G>T p.L1456F | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as COSV68180682; called by muse, mutect2, varscan2
- MTIF2 | c.1412A>G p.K471R | Missense Mutation (SNP) | VAF 95/591 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759302667; called by muse, mutect2, varscan2
- MYO7A | c.3055C>T p.R1019W | Missense Mutation (SNP) | VAF 93/569 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781904621; called by muse, mutect2, varscan2
- NBAS | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 53/606 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs776059952, COSV55731725; called by muse, mutect2
- NEFH | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs760541075, COSV60218807; called by muse, mutect2
- NEURL1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.838); catalogued as rs1295812148; called by muse, mutect2, varscan2
- NPHS1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 107/541 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.194); catalogued as COSV62287859; called by muse, mutect2, varscan2
- NPY1R | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV56713295; called by muse, mutect2, varscan2
- NT5C1B | c.502C>A p.P168T (on ENST00000359846 / NM_001199086.2; = p.P108T on NM_033253.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV58395644; called by muse, mutect2
- OR2B11 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs569352082, COSV59511418; called by muse, mutect2, varscan2
- OR52D1 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59487171; called by muse, mutect2, varscan2
- OTOGL | c.1824C>A p.S608R (on ENST00000547103; = p.S599R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs577298825; called by muse, mutect2, varscan2
- P2RY6 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs1321300314; called by muse, mutect2, varscan2
- PARD3 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 76/849 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs375911014; called by muse, mutect2
- PCDH15 | c.3508G>A p.D1170N | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57319922; called by muse, mutect2
- PDE8B | c.2020C>G p.L674V | Missense Mutation (SNP) | VAF 237/1062 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53736773; called by muse, mutect2, varscan2
- PTPRD | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 88/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61936192, COSV61975980; called by muse, mutect2, varscan2
- REG1B | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 71/410 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100521250; called by muse, mutect2, varscan2
- RIMS2 | c.3876G>T p.M1292I | Missense Mutation (SNP) | VAF 102/631 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV99153387; called by muse, mutect2, varscan2
- ROBO2 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 107/708 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59946476; called by muse, mutect2, varscan2
- TBX22 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64786441, COSV64786765; called by muse, mutect2, varscan2
- TESK2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.534); catalogued as COSV100517254, COSV59149476, COSV59156710; called by muse, mutect2
- TGFBR2 | c.1397-1G>T p.X466_splice | Splice Site (SNP) | VAF 241/1014 reads (24%) | catalogued as CS064462, COSV55464532; called by muse, mutect2, varscan2
- TMIE | c.458_462del p.K153Rfs*117 | Frame Shift Del (DEL) | VAF 116/663 reads (17%) | catalogued as rs1349277131; called by mutect2, pindel, varscan2
- TTF2 | c.1866G>T p.K622N | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV65634183; called by muse, mutect2, varscan2
- TUBA3C | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV67139053; called by muse, mutect2, varscan2
- UNC5C | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV71661019; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3209C>A p.T1070N | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ADCY10 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 198/907 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADGRA3 | c.2005G>T p.V669L | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALPK2 | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 90/483 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ANKRD12 | c.4810T>A p.Y1604N | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ASPRV1 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP8B4 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- BAZ1B | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 61/385 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- BCL11A | c.2150T>C p.F717S (on ENST00000335712 / NM_001365609.1; = p.F751S on NM_022893.4) | Missense Mutation (SNP) | VAF 98/613 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BTN1A1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 62/316 reads (20%) | called by muse, mutect2, varscan2
- C9orf72 | c.1384T>A p.F462I | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CACNA1H | c.1912G>C p.G638R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CACNA1S | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 147/903 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCDC30 | c.535G>A p.E179K (on ENST00000340612; = p.E136K on NM_001080850.3) | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CD200R1L | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CDH9 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CDRT1 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- COL24A1 | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A6 | c.3494A>T p.K1165M | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CYP1A2 | c.608T>G p.M203R | Missense Mutation (SNP) | VAF 93/860 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DCAF12L2 | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- DDX3X | c.384_408del p.D128Efs*84 (on ENST00000399959; = p.D129Efs*84 on NM_001356.5) | Frame Shift Del (DEL) | VAF 73/334 reads (22%) | called by mutect2, pindel
- DERA | c.482del p.S161Tfs*4 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | called by mutect2, pindel, varscan2
- DYNC1LI2 | c.884A>G p.H295R | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- EFEMP1 | c.1250C>G p.T417S | Missense Mutation (SNP) | VAF 54/508 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EXOC5 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 103/484 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FAT3 | c.5459C>T p.A1820V | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO36 | c.227del p.G76Vfs*5 | Frame Shift Del (DEL) | VAF 26/154 reads (17%) | called by mutect2, pindel, varscan2
- FEZF2 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGF3 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- GPR45 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 48/564 reads (9%) | called by muse, mutect2
- GPRASP2 | c.2062G>T p.A688S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GRAMD2A | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- GUCY1A2 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 62/447 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- H2BC1 | c.290del p.Q97Rfs*36 | Frame Shift Del (DEL) | VAF 49/325 reads (15%) | called by mutect2, pindel, varscan2
- H3C2 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 76/650 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IZUMO1R | c.603G>T p.Q201H (on ENST00000440961; = p.Q208H on NM_001199206.3) | Missense Mutation (SNP) | VAF 160/962 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT6A | c.5003C>T p.P1668L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- KEAP1 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNDC1 | c.1627G>T p.V543F | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LCOR | c.2345G>T p.C782F | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIF | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 76/604 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- LRIG3 | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- LRIT1 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPD4 | c.211+2T>A p.X71_splice | Splice Site (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- MAP7D3 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MVP | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 51/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.2248C>A p.P750T | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- NOTCH2 | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 242/1299 reads (19%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- OR10J1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR2M5 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 168/828 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51B2 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PASK | c.2401A>T p.T801S | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHAC1 | c.2255A>T p.Q752L | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PCDHGA2 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCNX2 | c.4714G>T p.D1572Y | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFRB | c.2088_2089insG p.K697Efs*81 | Frame Shift Ins (INS) | VAF 119/611 reads (19%) | called by mutect2, pindel, varscan2
- PDLIM4 | c.670+8G>T | Splice Region (SNP) | VAF 49/189 reads (26%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3385G>T p.A1129S | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHH2 | c.4336A>T p.N1446Y | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R7 | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); called by muse, mutect2
- PTPN4 | c.2532G>T p.K844N | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PTPRK | c.2443G>T p.D815Y (on ENST00000368215 / NM_001291984.2; = p.D816Y on NM_002844.4) | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PYM1 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 235/934 reads (25%) | called by muse, mutect2, varscan2
- RBM4 | c.627G>T p.L209F | Missense Mutation (SNP) | VAF 96/599 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM47 | c.150_173del p.N50_P58delinsK | In Frame Del (DEL) | VAF 34/382 reads (9%) | called by mutect2, pindel
- RGS9 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 98/741 reads (13%) | called by muse, mutect2, varscan2
- RNPEPL1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 90/547 reads (16%) | called by muse, mutect2, varscan2
- RXYLT1 | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 53/164 reads (32%) | called by muse, mutect2, varscan2
- SAMD9 | c.1019C>G p.S340* | Nonsense Mutation (SNP) | VAF 41/303 reads (14%) | called by muse, mutect2, varscan2
- SATB2 | c.1832G>A p.C611Y | Missense Mutation (SNP) | VAF 32/1200 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.198); called by muse, mutect2
- SCML4 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 99/534 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SEPTIN1 | c.393G>T p.K131N (on ENST00000321367; = p.K84N on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SFMBT2 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SIK3 | c.357C>G p.I119M (on ENST00000445177 / NM_001366686.2; = p.I125M on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC23A2 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 104/475 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A2 | c.1235C>A p.T412K | Missense Mutation (SNP) | VAF 106/495 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- SMARCA2 | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC6 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SREBF2 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 123/768 reads (16%) | called by muse, mutect2, varscan2
- ST18 | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 81/500 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAP2 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 67/813 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2
- TBX4 | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 63/379 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TCAF1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX13C | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TEX51 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 51/543 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- TOX | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAV12-2 | c.125_126del p.L42Qfs*6 | Frame Shift Del (DEL) | VAF 58/308 reads (19%) | called by pindel, varscan2
- UBR2 | c.3680C>T p.P1227L | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ULK3 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.148); called by muse, mutect2
- UQCRFS1 | c.504A>T p.K168N | Missense Mutation (SNP) | VAF 91/511 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WIPF2 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 73/525 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNT10B | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZFPM1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF260 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF678 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ABHD15 | c.27G>T p.A9= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1021673721; called by muse, mutect2, varscan2
- C9orf72 | c.1383T>A p.S461= | Silent (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- CACNA1S | c.5319G>A p.R1773= | Silent (SNP) | VAF 98/598 reads (16%) | catalogued as COSV62938415; called by muse, mutect2, varscan2
- CALCRL | c.948C>T p.L316= | Silent (SNP) | VAF 69/289 reads (24%) | catalogued as rs771341109; called by muse, mutect2, varscan2
- CCDC126 | c.411C>T p.G137= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, varscan2
- ERC2 | c.741C>T p.G247= | Silent (SNP) | VAF 45/388 reads (12%) | called by muse, mutect2, varscan2
- FAM171A1 | c.900G>T p.T300= | Silent (SNP) | VAF 47/289 reads (16%) | catalogued as COSV100968307; called by muse, mutect2, varscan2
- FOXI3 | c.1173C>T p.S391= | Silent (SNP) | VAF 83/565 reads (15%) | catalogued as rs774808218, COSV101230929, COSV67916871; called by muse, mutect2, varscan2
- HLA-DPB1 | c.57G>A p.L19= | Silent (SNP) | VAF 73/545 reads (13%) | called by muse, mutect2, varscan2
- HMCN2 | c.946C>A p.R316= | Silent (SNP) | VAF 63/483 reads (13%) | called by muse, mutect2, varscan2
- KIF13B | c.3045C>T p.V1015= | Silent (SNP) | VAF 115/526 reads (22%) | called by muse, mutect2, varscan2
- KRT35 | c.630G>T p.L210= | Silent (SNP) | VAF 56/443 reads (13%) | called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.453C>G p.T151= | Silent (SNP) | VAF 36/311 reads (12%) | called by muse, mutect2, varscan2
- LRRC19 | c.456G>A p.L152= | Silent (SNP) | VAF 87/468 reads (19%) | catalogued as COSV66259594; called by muse, mutect2, varscan2
- LRRC8C | c.1656C>T p.N552= | Silent (SNP) | VAF 51/248 reads (21%) | catalogued as rs1373872135, COSV64999315; called by muse, mutect2, varscan2
- MUC4 | c.14004G>A p.R4668= (on ENST00000463781 / NM_018406.7; = p.R432= on NM_004532.6) | Silent (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- MYPN | c.1689C>T p.P563= | Silent (SNP) | VAF 49/255 reads (19%) | catalogued as COSV62735338; called by muse, mutect2, varscan2
- OR11A1 | c.696G>C p.G232= | Silent (SNP) | VAF 42/189 reads (22%) | catalogued as rs1440636821; called by muse, mutect2, varscan2
- OR14C36 | c.339C>T p.L113= | Silent (SNP) | VAF 115/596 reads (19%) | catalogued as rs780619262; called by muse, mutect2, varscan2
- PHF2 | c.1959G>T p.P653= | Silent (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- PIK3R5 | c.456C>A p.P152= | Silent (SNP) | VAF 49/254 reads (19%) | catalogued as COSV52651141; called by muse, mutect2, varscan2
- ST6GAL1 | c.999G>T p.T333= | Silent (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- STAT4 | c.2235T>C p.Y745= | Silent (SNP) | VAF 43/431 reads (10%) | called by muse, mutect2, varscan2
- TIRAP | c.534G>T p.L178= | Silent (SNP) | VAF 54/297 reads (18%) | called by muse, mutect2, varscan2
- TRPM4 | c.1371G>T p.P457= | Silent (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- ZNF222 | c.843A>T p.A281= | Silent (SNP) | VAF 109/450 reads (24%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9527C>A | Intron (SNP) | VAF 328/1384 reads (24%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83760A>T | Intron (SNP) | VAF 93/607 reads (15%) | called by muse, mutect2, varscan2
- AL353753.1 | n.354C>T | RNA (SNP) | VAF 46/263 reads (17%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1983-551A>G | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- AP002495.1 | c.*22C>T | 3'UTR (SNP) | VAF 44/219 reads (20%) | called by muse, mutect2, varscan2
- AP1B1 | c.2766+19G>T | Intron (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- C2orf72 | c.*56G>A | 3'UTR (SNP) | VAF 91/527 reads (17%) | catalogued as rs546520299; called by muse, mutect2, varscan2
- CRB1 | c.3878+36G>C | Intron (SNP) | VAF 50/251 reads (20%) | catalogued as rs1404083213; called by muse, mutect2, varscan2
- CYFIP1 | c.1675-106C>A | Intron (SNP) | VAF 63/555 reads (11%) | called by muse, mutect2, varscan2
- DNAJC5 | c.-8A>T | 5'UTR (SNP) | VAF 137/653 reads (21%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8312G>A | Intron (SNP) | VAF 52/242 reads (21%) | called by muse, mutect2, varscan2
- FANCA | c.2779-753A>G | Intron (SNP) | VAF 44/243 reads (18%) | called by muse, mutect2, varscan2
- GCSAML | c.-56-10371G>T | Intron (SNP) | VAF 71/378 reads (19%) | called by muse, mutect2, varscan2
- GORAB | c.*1310A>T | 3'UTR (SNP) | VAF 92/336 reads (27%) | called by muse, mutect2, varscan2
- GPT2 | c.1213-12A>T | Intron (SNP) | VAF 142/843 reads (17%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.288C>T | RNA (SNP) | VAF 55/678 reads (8%) | catalogued as rs1215125359; called by muse, mutect2
- MCRS1 | c.10+11G>A | Intron (SNP) | VAF 153/651 reads (24%) | called by muse, mutect2, varscan2
- NRG1 | c.700+603C>G | Intron (SNP) | VAF 31/287 reads (11%) | called by muse, mutect2, varscan2
- PEX11B | chr1:145919812 C>T | 5'Flank (SNP) | VAF 118/878 reads (13%) | called by muse, mutect2, varscan2
- RHOC | c.-31C>T | 5'UTR (SNP) | VAF 66/402 reads (16%) | called by muse, mutect2, varscan2
- SH3BP2 | c.239+478G>T | Intron (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928420 del G | 3'Flank (DEL) | VAF 62/430 reads (14%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.3519+702G>C | Intron (SNP) | VAF 71/486 reads (15%) | called by muse, mutect2, varscan2
- SYNE2 | c.19333+883T>C | Intron (SNP) | VAF 127/797 reads (16%) | called by muse, mutect2, varscan2
- SYNE2 | c.19333+884G>T | Intron (SNP) | VAF 126/794 reads (16%) | called by muse, mutect2, varscan2
- TMEM184B | c.193-724G>T | Intron (SNP) | VAF 29/156 reads (19%) | catalogued as rs1017089978; called by muse, mutect2, varscan2
- TMEM198 | c.-83T>C | 5'UTR (SNP) | VAF 50/296 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.*597G>T | 3'UTR (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- TPM3 | c.244-6916G>A | Intron (SNP) | VAF 88/510 reads (17%) | catalogued as rs961203414; called by muse, mutect2, varscan2
- UBTFL2 | n.116C>T | RNA (SNP) | VAF 33/317 reads (10%) | catalogued as rs760457514; called by muse, mutect2, varscan2
- ZMPSTE24 | c.*10G>T | 3'UTR (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- ZNF26 | c.34-5339G>T | Intron (SNP) | VAF 128/492 reads (26%) | called by muse, mutect2, varscan2
